Somatic mutation profile of tumor specimen MP2PRT-PAVGDA-TMP1-A (aliquot MP2PRT-PAVGDA-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVGDA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,870 days).
Specimen MP2PRT-PAVGDA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 496b2293-dcaa-4876-925e-c0a755a364d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVGDA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVGDA-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0edca941-abb5-4f92-87f6-a147a047e4ca

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH4A1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 188/464 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as rs757819366, COSV51895334; called by muse, mutect2, varscan2
- CACNA2D3 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs768809129, COSV55526000, COSV99872251; called by muse, varscan2
- CLEC3B | c.207G>A p.T69= | Splice Region (SNP) | VAF 106/267 reads (40%) | catalogued as rs904279160; called by muse, mutect2, varscan2
- SLC30A10 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV63075506; called by muse, mutect2
- SLC35F1 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs575430378; called by muse, mutect2, varscan2
- SYNE1 | c.16229G>A p.R5410Q (on ENST00000367255 / NM_182961.4; = p.R5339Q on NM_033071.3) | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs776100963, COSV54983607, COSV99563602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK7 | c.1053C>A p.S351R | Missense Mutation (SNP) | VAF 252/646 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FAAP100 | c.1570A>C p.M524L | Missense Mutation (SNP) | VAF 212/484 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by mutect2, varscan2
- HARS2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MAP3K8 | c.767_769delinsAG p.P256Qfs*18 | Frame Shift Del (DEL) | VAF 55/161 reads (34%) | called by pindel, varscan2*
- MYO3A | c.2522G>A p.S841N | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.196); called by muse, mutect2
- TDRD15 | c.1726T>C p.F576L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DLGAP1 | c.732C>T p.S244= | Silent (SNP) | VAF 30/472 reads (6%) | catalogued as rs1051462111; called by muse, mutect2
- DMKN | c.1050G>A p.T350= | Silent (SNP) | VAF 86/207 reads (42%) | catalogued as rs768991824; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406871 TTCAC>G | Silent (DEL) | VAF 60/89 reads (67%) | called by pindel, varscan2*
- PRR14L | c.1800C>T p.S600= | Silent (SNP) | VAF 9/279 reads (3%) | called by muse, mutect2
- TDRD15 | c.2511C>T p.Y837= | Silent (SNP) | VAF 69/201 reads (34%) | called by muse, mutect2, varscan2
